Somatic mutation profile of tumor specimen MP2PRT-PATWPR-TMP1-A (aliquot MP2PRT-PATWPR-TMP1-A-1-0-D-A82B-36) from MP2PRT case MP2PRT-PATWPR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,289 days).
Specimen MP2PRT-PATWPR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 007c4dcb-d33a-4bce-8bc7-d3307d3accae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATWPR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATWPR-NB1-A-1-0-D-A82B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3ce92e9-9078-4255-aa77-665879e0205d

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, Frame Shift Del 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1G | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 161/448 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1222506608, COSV61728898; called by muse, mutect2, varscan2
- TTN | c.55892C>T p.P18631L (on ENST00000591111; = p.P11207L on NM_003319.4) | Missense Mutation (SNP) | VAF 144/487 reads (30%) | PolyPhen probably damaging (0.999); catalogued as rs760277470, COSV100612870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRL3 | c.199del p.R67Vfs*43 | Frame Shift Del (DEL) | VAF 191/817 reads (23%) | called by mutect2, pindel, varscan2
- DPH5 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- E2F1 | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 124/344 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EBF1 | c.1393_1394delinsTGAGGGCTACAGGGGTTC p.V465* | Nonsense Mutation (INS) | VAF 113/636 reads (18%) | called by pindel, varscan2*
- NHSL2 | c.1181C>A p.P394Q (on ENST00000510661; = p.P760Q on NM_001013627.2) | Missense Mutation (SNP) | VAF 161/481 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CA3 | c.177C>T p.I59= | Silent (SNP) | VAF 176/747 reads (24%) | called by muse, mutect2, varscan2
- HUNK | c.1785C>T p.S595= | Silent (SNP) | VAF 280/1199 reads (23%) | catalogued as rs531214638; called by muse, mutect2
- PCDHB15 | c.369G>T p.V123= | Silent (SNP) | VAF 159/504 reads (32%) | catalogued as COSV51423784; called by muse, mutect2, varscan2
- ZNF423 | c.1623C>T p.T541= (on ENST00000563137 / NM_001379286.1; = p.T533= on NM_015069.4) | Silent (SNP) | VAF 164/374 reads (44%) | catalogued as rs558769719, COSV52177621; called by muse, varscan2
- JHY | c.864+755C>T | Intron (SNP) | VAF 64/153 reads (42%) | catalogued as rs376019049; called by muse, mutect2, varscan2
